Gene-level copy-number profile of tumor specimen TCGA-3B-A9HX-01A from TCGA case TCGA-3B-A9HX, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 70.2 years (25,627 days).
Specimen TCGA-3B-A9HX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.1d4063b5-378d-4782-bdc4-52115de1a25a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3B-A9HX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/62b7bb5f-8815-47bd-bc0f-f44a6e8f9624

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 1,852; copy number 2: 18,058; copy number 3: 18,570; copy number 4: 17,911; copy number 5: 1,959; copy number 6: 662; copy number 7: 474; copy number 8: 123; copy number 9: 108; copy number 10: 5; copy number 13: 11; copy number 16: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3B-A9HX-01A-11D-A38Y-01): tumor purity 0.53, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:38,567,715–38,936,199, 7 genes (within-gene range 0–4): LINC00366, PRDX3P3, FREM2, RNU6-56P, FREM2-AS1, PLA2G12AP2, ANKRD26P2.
- chr13:48,134,358–50,906,856, 60 genes (within-gene range 0–1): POLR2KP2, ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5, DLEU1, AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1.
- chr19:23,739,195–23,758,891, 1 gene (within-gene range 0–2): ZNF681.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 127 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:84,371,393–84,380,189, 1 gene, copy number 9: AC104063.1.
- chr7:8,433,609–8,752,961, 1 gene, copy number 10 (within-gene range 4–10): NXPH1.
- chr8:46,810,696–46,907,309, 9 genes, copy number 13 (within-gene range 3–13): AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3.
- chr8:139,096,305–139,127,953, 3 genes, copy number 16 (within-gene range 5–16): AC027541.1, AC100807.1, AC100807.2.
- chr9:75,579,669–75,724,575, 2 genes, copy number 9: AL353780.1, OTX2P1.
- chr16:52,198,012–52,227,956, 1 gene, copy number 13 (within-gene range 4–13): AC007333.2.
- chr19:6,135,247–6,193,094, 2 genes, copy number 9 (within-gene range 2–9): ACSBG2, AC011471.1.
- chr19:9,689,924–10,074,135, 20 genes, copy number 9 (within-gene range 2–9): ZNF812P, AC008759.3, AC008759.1, AC008759.2, ZNF846, AC008752.3, UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2, COL5A3, AC008742.1, RDH8, C3P1, MIR5589.
- chr19:10,871,553–11,326,996, 18 genes, copy number 9 (within-gene range 2–9): CARM1, YIPF2, TIMM29, SMARCA4, AC011442.1, RN7SL192P, AC006127.1, LDLR, MIR6886, SPC24, KANK2, DOCK6, AC011472.1, AC011472.5, AC011472.4, ANGPTL8, TSPAN16, AC011472.2.
- chr19:12,195,015–12,640,098, 28 genes, copy number 9: AC012618.3, ZNF44, AC012618.1, AC012618.2, ZNF563, ZNF442, RPS29P23, AC008758.4, AC008758.3, ZNF799, AC008758.5, ZNF443, AC008758.6, AC008758.2, ZNF709, AC008758.1, MTND2P40, MTCO1P27, MTCO2P27, MTATP6P27, PPIAP20, ZNF564, AC010422.6, AC010422.4, AC010422.1, PGK1P2, ZNF490, ZNF791.
- chr19:13,116,862–13,633,025, 9 genes, copy number 9 (within-gene range 2–9): NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42, CACNA1A.
- chr19:16,630,743–16,712,434, 6 genes, copy number 9 (within-gene range 2–9): AC024075.3, SMIM7, AC024075.2, AC024075.1, TMEM38A, AC008737.2.
- chr19:21,932,958–22,010,949, 4 genes, copy number 10: ZNF208, MTDHP2, AC003973.2, BNIP3P28.
- chr19:41,449,520–41,501,223, 1 gene, copy number 13 (within-gene range 2–13): PCAT19.
- chr19:46,143,106–46,260,858, 10 genes, copy number 9 (within-gene range 2–9): IGFL2, AC006262.2, IGFL2-AS1, IGFL1P1, AC006262.1, RPL12P41, AC006262.3, IGFL1, AC006262.4, IGFL1P2.
- chr19:49,289,638–49,417,990, 9 genes, copy number 9 (within-gene range 2–9): SLC6A16, MIR4324, AC011450.1, CD37, TEAD2, AC010524.1, DKKL1, AC010643.1, KASH5.
- chr19:57,571,566–57,612,722, 3 genes, copy number 9: ZNF416, ZIK1, ZNF530.

Autosomal genes at a single copy (total copy number 1): 1,844. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
